MMRF case MMRF_2143 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/738e0773-2eeb-44a6-9dc9-ecb361ccf3bb

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 841 days (2.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,535 days); ISS stage: II; Days to last known disease status: 841 days (2.3 years); Days to last follow up: 841 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 42 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 42 days; Days to treatment end: 841 days (2.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 841.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 558 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.2 mg/dL; Immunoglobulin G 25.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2.49 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 30 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 104 (ECOG 1): M Protein 0.56 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 5.4 g/dL; Glucose 10.8 mmol/L.
- Day 168 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 36.2 mmol/L.
- Day 230 (ECOG 1): M Protein 0.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 14.6 mmol/L.
- Day 342 (ECOG 0): Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 13.9 mmol/L.
- Day 433 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.29 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 191 ×10⁹/L.
- Day 553: Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 7.7 g/dL; Glucose 11.9 mmol/L.
- Day 713 (ECOG 1): Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.1 mmol/L; Albumin 26 g/L; Total Protein 6.3 g/dL; Glucose 17.1 mmol/L.

Other clinical attributes
- Day -7: Weight: 95 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_2143_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2143_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
